Somatic mutation profile of tumor specimen TCGA-DM-A28M-01A (aliquot TCGA-DM-A28M-01A-12D-A16V-10) from TCGA case TCGA-DM-A28M, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.1 years (23,043 days).
Specimen TCGA-DM-A28M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cee521a-4b32-47e9-b2aa-5070b1c7fef5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A28M-10A (Blood Derived Normal), aliquot TCGA-DM-A28M-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccde4a97-19fe-453f-a865-62636d50974f

The open-access MAF lists 98 somatic variants for this specimen: 73 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 24, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2828C>A p.S943* | Nonsense Mutation (SNP) | VAF 15/109 reads (14%) | catalogued as rs1554084512, CM021064, CM086470, COSV57334177, COSV57340756, COSV57390748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.3773dup p.L1258Ffs*7 | Frame Shift Ins (INS) | VAF 50/222 reads (23%) | catalogued as rs121908789; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 147/211 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 37/72 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POMGNT1 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 31/61 reads (51%) | PolyPhen probably damaging (1); catalogued as rs267606962, CM035932, CM095808, COSV64340932; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.5324C>T p.A1775V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.362); catalogued as rs368943608; called by muse, mutect2, varscan2
- AKAP12 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 95/140 reads (68%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as rs764470310, COSV53581988; called by muse, mutect2, varscan2
- ANO2 | c.2099A>G p.K700R (on ENST00000356134 / NM_001278597.3; = p.K704R on NM_001278596.3) | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV59043172; called by muse, mutect2, varscan2
- APLNR | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200854787, COSV57242011; called by muse, mutect2, varscan2
- ARHGEF10 | c.3515G>A p.G1172E (on ENST00000398564; = p.G1147E on NM_014629.4) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV50677843; called by muse, mutect2, varscan2
- ASB18 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs538462078, COSV58235829; called by muse, mutect2, varscan2
- ASH1L | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 122/297 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64213705; called by muse, mutect2, varscan2
- ATP1B4 | c.63+1G>A p.X21_splice | Splice Site (SNP) | VAF 34/41 reads (83%) | catalogued as rs756219983, COSV54315016; called by muse, mutect2, varscan2
- BEND4 | c.996G>T p.E332D | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV72469060; called by muse, mutect2, varscan2
- CCDC40 | c.2792C>T p.T931M | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs202141933, COSV66478695; called by muse, mutect2, varscan2
- CHST8 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370247769, COSV52863173; called by muse, mutect2, varscan2
- CTC1 | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs772328631, COSV59855497; called by muse, mutect2, varscan2
- DOCK8 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.9); catalogued as rs1318020471, COSV66635586, COSV66636057; called by muse, mutect2
- FBXL7 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as rs761869950, COSV61645513; called by muse, mutect2, varscan2
- GLI3 | c.2701G>T p.D901Y | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101230067; called by muse, mutect2, varscan2
- GMEB2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 96/145 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs370349975; called by muse, mutect2, varscan2
- GPR179 | c.4049C>T p.A1350V (on ENST00000621958; = p.A1349V on NM_001004334.4) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs200212196; called by muse, mutect2, varscan2
- IGHG2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs587758396; called by muse, mutect2, varscan2
- JPH4 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100689405; called by muse, varscan2
- KIAA1522 | c.2189C>T p.P730L (on ENST00000373480 / NM_001198972.2; = p.P789L on NM_020888.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as rs760884113, COSV99615150; called by muse, mutect2, varscan2
- KIAA1549L | c.4478G>A p.R1493Q (on ENST00000321505; = p.R1790Q on NM_012194.3) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs759144156, COSV58596153; called by muse, mutect2, varscan2
- KLHL40 | c.1661G>T p.S554I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV55137321, COSV55137830; called by muse, mutect2, varscan2
- KNCN | c.250G>A p.A84T (on ENST00000481882 / NM_001322255.2; = p.A61T on NM_001097611.1) | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs761613949, COSV53815612; called by muse, mutect2, varscan2
- LCMT2 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99980087, COSV99980259; called by muse, mutect2, varscan2
- LRP1B | c.1991G>A p.W664* | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | catalogued as COSV101252543, COSV101261383; called by muse, mutect2, varscan2
- MAFK | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs372119240; called by muse, varscan2
- MAPKAP1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.926); catalogued as rs747216426, COSV56374389; called by muse, mutect2, varscan2
- MPO | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV56568951; called by muse, mutect2, varscan2
- MUC16 | c.38113T>G p.F12705V | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV67493718; called by muse, mutect2, varscan2
- MUC16 | c.30236C>T p.T10079I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.158); catalogued as COSV67493722; called by muse, mutect2, varscan2
- MYO1F | c.1854A>C p.R618S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV57800229; called by muse, mutect2, varscan2
- MYOF | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 56/113 reads (50%) | catalogued as rs751178586, COSV63703839; called by muse, mutect2, varscan2
- MYOF | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as rs200304153, COSV100826110; called by muse, mutect2, varscan2
- OTOF | c.4991C>T p.A1664V (on ENST00000272371 / NM_194248.3; = p.A897V on NM_004802.4) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1410079943, COSV55519537, COSV99718187; called by muse, mutect2, varscan2
- PAPPA | c.3646C>A p.P1216T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV60291728; called by muse, mutect2, varscan2
- PCDHB13 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); catalogued as rs1417066543, COSV53399303; called by muse, mutect2, varscan2
- PKD2 | c.2819G>T p.R940L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs756158263, COSV52941283, COSV99417807; called by muse, mutect2, varscan2
- PPFIA2 | c.2542C>G p.Q848E | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV100335359; called by muse, mutect2, varscan2
- PRKAB1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs772422545, COSV57555577; called by muse, mutect2, varscan2
- PSMB1 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV51531952; called by muse, mutect2, varscan2
- PTCD1 | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs535281099, COSV52864767; called by muse, mutect2, varscan2
- RIMKLB | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 97/161 reads (60%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as rs754337339, COSV55237732; called by muse, mutect2, varscan2
- RNF25 | c.287+1G>A p.X96_splice | Splice Site (SNP) | VAF 51/97 reads (53%) | catalogued as COSV55309692; called by muse, mutect2, varscan2
- RNF7 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56422174; called by muse, mutect2, varscan2
- SALL4 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs371371697, COSV53850705; called by mutect2, varscan2
- SCD | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs200497654, COSV64853573, COSV64853598; called by muse, mutect2, varscan2
- SCN9A | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as rs201247595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1D | c.188_190del p.F63del (on ENST00000338555; = p.F227del on NM_001130413.4) | In Frame Del (DEL) | VAF 42/101 reads (42%) | catalogued as rs770851489; called by pindel, varscan2
- SF1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as rs111552365, COSV57114945; called by muse, mutect2, varscan2
- SLC32A1 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV54147552, COSV54148376; called by muse, mutect2, varscan2
- SLC35G5 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs532136763, COSV55312683; called by muse, mutect2, varscan2
- SMAD2 | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51054301; called by muse, mutect2, varscan2
- SPHKAP | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 146/265 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV100763914, COSV60894054; called by muse, mutect2, varscan2
- SSTR4 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1213927042, COSV54798322, COSV99658418; called by muse, mutect2, varscan2
- STK36 | c.2879G>T p.C960F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV55330694; called by muse, mutect2, varscan2
- STYXL2 | c.2677A>T p.I893L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV54810067; called by muse, mutect2, varscan2
- SUFU | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV64020305; called by muse, mutect2, varscan2
- TSSK1B | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs948968186, COSV66815715; called by muse, mutect2, varscan2
- UBA3 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1030790749, COSV100734643, COSV62741522; called by muse, mutect2, varscan2
- UBE4B | c.3374T>A p.L1125H (on ENST00000343090 / NM_001105562.3; = p.L996H on NM_006048.5) | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53542266; called by muse, mutect2, varscan2
- VPS26A | c.860T>C p.F287S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54969625; called by muse, mutect2, varscan2
- ZFPL1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs759578792, COSV51869641; called by muse, varscan2
- ZNF213 | c.1345A>G p.S449G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.713); catalogued as COSV101206056; called by mutect2, varscan2
- ZNF808 | c.334A>G p.N112D | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1375102059, COSV63120480; called by muse, varscan2
- ZNF862 | c.2629G>A p.V877M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs771555716, COSV99783842; called by mutect2, varscan2
- APC | c.4240del p.V1414* | Frame Shift Del (DEL) | VAF 58/106 reads (55%) | called by mutect2, pindel, varscan2
- MED27 | c.597del p.V200* | Frame Shift Del (DEL) | VAF 58/116 reads (50%) | called by mutect2, pindel, varscan2
- SMAD3 | c.289_292del p.L97Tfs*18 | Frame Shift Del (DEL) | VAF 13/19 reads (68%) | called by mutect2, varscan2
- AFG1L | c.1131G>A p.P377= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs770762851, COSV64558321; called by muse, mutect2
- BRCA2 | c.6291G>A p.T2097= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs369340015; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHST11 | c.411C>T p.V137= | Silent (SNP) | VAF 59/94 reads (63%) | catalogued as COSV57994788; called by muse, mutect2, varscan2
- EPG5 | c.3663C>T p.S1221= | Silent (SNP) | VAF 40/52 reads (77%) | catalogued as COSV56355974; called by muse, mutect2, varscan2
- FAM13C | c.285C>T p.I95= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99514652; called by muse, mutect2, varscan2
- FAM83E | c.486C>T p.D162= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1167259569, COSV50032407; called by muse, mutect2, varscan2
- FNDC1 | c.3159G>A p.S1053= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs765369296, COSV51947772; called by muse, mutect2, varscan2
- HERPUD2 | c.645A>G p.T215= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs758135857, COSV100258148; called by muse, mutect2, varscan2
- KCNK9 | c.459C>T p.D153= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs776045672, COSV100271749; called by muse, mutect2, varscan2
- LLGL2 | c.1359G>A p.S453= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs368604286; called by muse, mutect2, varscan2
- MAN2A2 | c.2052C>T p.A684= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as rs756445163, COSV64639895; called by muse, mutect2, varscan2
- MBTPS1 | c.1191C>T p.G397= | Silent (SNP) | VAF 44/74 reads (59%) | catalogued as rs72799287, COSV58572576; called by muse, mutect2, varscan2
- MN1 | c.3720C>T p.D1240= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV56558967; called by muse, mutect2, varscan2
- NRXN1 | c.3372G>A p.T1124= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs200769389, COSV58446288; called by muse, mutect2, varscan2
- PITRM1 | c.2004C>T p.F668= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV56539726; called by muse, mutect2, varscan2
- RIMKLA | c.696C>T p.G232= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as rs780221639, COSV68909986; called by muse, mutect2, varscan2
- RNF207 | c.975G>A p.T325= | Silent (SNP) | VAF 50/66 reads (76%) | catalogued as rs776199469, COSV65007733; called by muse, mutect2, varscan2
- ROBO1 | c.2019G>T p.L673= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV71398577; called by muse, mutect2, varscan2
- SCRIB | c.1071G>A p.T357= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs200653689; called by muse, mutect2, varscan2
- SIPA1L3 | c.4521A>G p.K1507= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99730551; called by muse, mutect2, varscan2
- TIRAP | c.195G>A p.T65= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as rs371062583; called by muse, mutect2, varscan2
- USP9X | c.270G>T p.P90= | Silent (SNP) | VAF 173/214 reads (81%) | catalogued as COSV61075121, COSV61075587; called by muse, mutect2, varscan2
- VPS13A | c.7332C>T p.A2444= | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as rs747089927, COSV62439060; called by muse, mutect2, varscan2
- ZAP70 | c.273C>T p.P91= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs920302301, COSV99385972; called by muse, mutect2, varscan2
- MYO3B | c.-2C>T | 5'UTR (SNP) | VAF 94/184 reads (51%) | catalogued as rs962858017, COSV100511872; called by muse, mutect2, varscan2
